TCGA case TCGA-VN-A88N — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: NCI Urologic Oncology Branch. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e9a4c770-665f-454b-81f7-b8ae3f1e154e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 62.1 years (22,695 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC clinical M: M0; AJCC pathologic T: T2c; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 50; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Overlapping/multiple zones.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (6 entries)
- Day -117 (initial diagnosis): Days to imaging: -117 days; Imaging type: MRI; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 98 (initial diagnosis): Days to imaging: 98 days; Imaging type: Bone Scan, NOS; Imaging result: Indeterminate.
- Day 98 (initial diagnosis): Days to imaging: 98 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Days to follow up: 176 days; Disease response: Tumor Free.
- Days to follow up: 472 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 766 days (2.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0 ng/mL (day 176).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VN-A88N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-VN-A88N-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 20.
- Sample TCGA-VN-A88N-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Equivocal; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 3.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 766 days; disease-specific survival: no event (censored), 766 days; disease-free interval: no event (censored), 766 days; progression-free interval: no event (censored), 766 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VN-A88N-01A-11D-A363-01): tumor purity 0.76, ploidy 1.98, whole-genome doublings 0.
